Somatic mutation profile of tumor specimen MMRF_2770_1_BM_CD138pos (aliquot MMRF_2770_1_BM_CD138pos_T1_KHS5U_L15721) from MMRF case MMRF_2770, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2770_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b96ac105-e217-4dbd-8705-3a488507c750.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2770_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2770_1_PB_WBC_C3_KHS5U_L15765; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51ecfcac-1b62-4323-9b86-441864ae6578

The open-access MAF lists 113 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 25, Intron 14, Silent 13, RNA 6, 5'UTR 4, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 2, 5'Flank 2, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD1 | c.6022C>T p.P2008S (on ENST00000520002; = p.P2007S on NM_033225.6) | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV59383074; called by muse, mutect2, varscan2
- CTC1 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371670247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDX47 | c.1325A>G p.N442S | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs1388348750; called by muse, mutect2
- DSG3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128517; called by muse, mutect2, varscan2
- DYTN | c.803C>G p.S268C | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs764910729, COSV71752694; called by muse, mutect2, varscan2
- HCN1 | c.1734G>A p.M578I | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100299382; called by muse, mutect2, varscan2
- HMCN1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54899482; called by muse, mutect2, varscan2
- IGHV2-70 | c.308T>G p.M103R | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs534782395; called by muse, varscan2
- IGHV2-70 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs368831727; called by muse, varscan2
- IGHV2-70 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs747883300; called by muse, varscan2
- KANK2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754512529, COSV62009478; called by muse, mutect2, varscan2
- KLHL6 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs148924291; called by muse, mutect2, varscan2
- LSM14B | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 142/294 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs373041672; called by muse, mutect2, varscan2
- MAGI1 | c.3466G>C p.G1156R (on ENST00000402939 / NM_001033057.2; = p.G1185R on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58323884; called by muse, mutect2, varscan2
- MYBPC2 | c.2509C>G p.P837A | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV63094365; called by muse, mutect2
- NFKBIE | c.759_762del p.Y254Sfs*13 (on ENST00000275015; = p.Y115Sfs*13 on NM_004556.3) | Frame Shift Del (DEL) | VAF 33/102 reads (32%) | catalogued as rs755160004; called by mutect2, pindel, varscan2
- PLXNA4 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as rs1012133330; called by muse, mutect2, varscan2
- POT1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931824; called by muse, mutect2, varscan2
- SERPINB7 | c.253dup p.S85Ffs*2 | Frame Shift Ins (INS) | VAF 14/75 reads (19%) | catalogued as rs1434994276; called by mutect2, pindel, varscan2
- SOS2 | c.2838A>T p.L946F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs532833599, COSV53563838; called by muse, mutect2, varscan2
- ST8SIA2 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 58/252 reads (23%) | PolyPhen benign (0.125); catalogued as COSV99184466; called by muse, mutect2, varscan2
- SYNE2 | c.3571T>G p.F1191V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV59966364; called by muse, mutect2, varscan2
- ULK4 | c.3283G>A p.V1095M | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs964617718; called by muse, mutect2, varscan2
- YLPM1 | c.761dup p.G255Wfs*3 | Frame Shift Ins (INS) | VAF 14/78 reads (18%) | catalogued as rs760065689; called by mutect2, varscan2
- ZFP91 | c.1315T>A p.F439I | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV60161466; called by muse, mutect2
- AIPL1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AQR | c.1900dup p.Y634Lfs*18 | Frame Shift Ins (INS) | VAF 7/77 reads (9%) | called by mutect2, pindel
- EFHB | c.2424A>T p.E808D | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- EPSTI1 | c.692C>G p.A231G (on ENST00000398762 / NM_001330543.2; = p.A220G on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- FSTL4 | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GDF2 | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- LRP2 | c.4816G>A p.D1606N | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFSD5 | c.195A>T p.K65N | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MGAM2 | c.1522C>G p.L508V | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MMP24 | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 57/184 reads (31%) | called by muse, mutect2, varscan2
- OR52B4 | c.891A>C p.K297N | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- PADI1 | c.1240G>T p.V414F | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POU3F2 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, varscan2
- RC3H1 | c.2523+1G>A p.X841_splice | Splice Site (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- SCN8A | c.5422C>A p.L1808M | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGCB | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SH3YL1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SLC25A13 | c.706A>T p.I236F | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TFE3 | c.996G>C p.E332D | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TNFAIP8 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 106/574 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF30 | c.10-1G>T p.X4_splice | Splice Site (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- ZNF583 | c.1016T>G p.L339R | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZXDC | c.154_187del p.G52Rfs*61 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | called by mutect2, pindel
- ABCA13 | c.5559C>T p.G1853= | Silent (SNP) | VAF 82/206 reads (40%) | called by muse, mutect2
- ACO2 | c.129C>T p.I43= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- FASTKD3 | c.1320C>T p.F440= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs767650257; called by muse, mutect2, varscan2
- GJA4 | c.351G>A p.P117= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs751546404; called by muse, mutect2, varscan2
- MMP28 | c.225C>T p.S75= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as rs765062835; called by muse, mutect2, varscan2
- NOTCH1 | c.5268G>T p.L1756= | Silent (SNP) | VAF 61/269 reads (23%) | catalogued as rs771182004; called by muse, mutect2, varscan2
- PADI3 | c.1077G>A p.A359= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs148137946, COSV100968389; called by muse, mutect2, varscan2
- PLEKHH3 | c.1977C>T p.F659= | Silent (SNP) | VAF 115/228 reads (50%) | catalogued as rs762924915; called by muse, mutect2, varscan2
- RRP9 | c.573C>T p.A191= | Silent (SNP) | VAF 38/129 reads (29%) | catalogued as rs747736507, COSV51754159; called by muse, mutect2, varscan2
- SCN3B | c.573C>A p.A191= | Silent (SNP) | VAF 77/176 reads (44%) | catalogued as COSV54800514; called by muse, mutect2, varscan2
- SEMA6D | c.33G>T p.L11= | Silent (SNP) | VAF 224/383 reads (58%) | catalogued as COSV60377171; called by muse, mutect2, varscan2
- TNFRSF11A | c.1059C>G p.P353= | Silent (SNP) | VAF 41/238 reads (17%) | catalogued as rs754454481; called by muse, mutect2, varscan2
- TSPAN15 | c.786C>T p.I262= | Silent (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- AKAP1 | c.*340C>T | 3'UTR (SNP) | VAF 14/63 reads (22%) | catalogued as rs976553316; called by muse, mutect2, varscan2
- ANOS1 | c.*3868C>A | 3'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- APBB1 | c.*301C>G | 3'UTR (SNP) | VAF 94/199 reads (47%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.138G>A | RNA (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- BABAM1 | c.699+9G>T | Intron (SNP) | VAF 57/165 reads (35%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.1164-88C>T | Intron (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- C12orf77 | n.1379C>T | RNA (SNP) | VAF 23/53 reads (43%) | catalogued as rs1327004993; called by muse, mutect2, varscan2
- C1orf174 | c.-75T>C | 5'UTR (SNP) | VAF 23/80 reads (29%) | catalogued as rs541873858; called by muse, mutect2, varscan2
- CAPN11 | c.1805-50G>A | Intron (SNP) | VAF 43/256 reads (17%) | catalogued as rs1173755755; called by muse, mutect2, varscan2
- CARMIL3 | c.2305-44T>C | Intron (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- CCDC117 | c.*1365C>G | 3'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- CSKMT | c.-221T>C | 5'UTR (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- DSEL | c.*462T>G | 3'UTR (SNP) | VAF 71/97 reads (73%) | catalogued as rs935602674; called by muse, mutect2, varscan2
- FAIM2 | c.*3244G>A | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- FAM20C | c.1254-70C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- FAM43B | c.*6G>A | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- FZD8 | c.*801G>T | 3'UTR (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- GLP2R | c.*1934_*1940del | 3'UTR (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- GORASP2 | c.*95G>A | 3'UTR (SNP) | VAF 7/103 reads (7%) | catalogued as rs977851153; called by muse, mutect2
- GPBP1L1 | c.*607C>A | 3'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- H2BC9 | c.*28C>G | 3'UTR (SNP) | VAF 102/238 reads (43%) | called by muse, mutect2, varscan2
- HMGN4 | c.*364A>G | 3'UTR (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- HNRNPK | c.214-87G>A | Intron (SNP) | VAF 48/622 reads (8%) | catalogued as COSV100699104; called by muse, mutect2
- IQGAP1 | c.*1840G>A | 3'UTR (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- KREMEN1 | chr22:29145472 C>T | 3'Flank (SNP) | VAF 58/139 reads (42%) | called by muse, mutect2, varscan2
- LGALS8 | c.-104+97A>C | Intron (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- LRRC55 | c.*2083A>G | 3'UTR (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- MFAP3L | c.*3159A>G | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- MIR493 | n.1C>T | RNA (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- MYO1E | c.-140G>C | 5'UTR (SNP) | VAF 107/171 reads (63%) | called by muse, mutect2, varscan2
- MYO7A | c.6354+125G>A | Intron (SNP) | VAF 21/141 reads (15%) | called by muse, mutect2, varscan2
- NBEAL1 | c.*2111G>T | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- NHSL1 | c.*127G>A | 3'UTR (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- OR51T1 | chr11:4881821 G>T | 5'Flank (SNP) | VAF 14/60 reads (23%) | catalogued as COSV59025173; called by mutect2, varscan2
- PAPPA | c.*180C>T | 3'UTR (SNP) | VAF 47/125 reads (38%) | catalogued as rs1042508485; called by muse, mutect2, varscan2
- PHC2 | c.2423-1024T>G | Intron (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- PIK3CD | c.*1343dup | 3'UTR (INS) | VAF 38/100 reads (38%) | called by mutect2, pindel, varscan2
- PLEKHA8P1 | n.1744G>A | RNA (SNP) | VAF 64/219 reads (29%) | called by muse, mutect2, varscan2
- PNKD | c.236+1184_236+1205delinsGG | Intron (DEL) | VAF 31/70 reads (44%) | called by pindel, varscan2*
- POU3F3 | c.*699G>A | 3'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- RABGGTB | c.111+17dup | Intron (INS) | VAF 8/34 reads (24%) | catalogued as rs770430958; called by mutect2, varscan2
- RARG | c.1019-32C>T | Intron (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- RPL37 | c.*2756G>A | 3'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, varscan2
- SMC4 | chr3:160400262 G>A | 5'Flank (SNP) | VAF 12/281 reads (4%) | called by muse, mutect2
- SSPOP | n.10456G>A | RNA (SNP) | VAF 11/89 reads (12%) | catalogued as rs750475806, COSV100948262; called by muse, mutect2
- SVIL2P | n.820C>T | RNA (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- TAPBP | c.-106A>G | 5'UTR (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- TCF3 | c.-39-22T>A | Intron (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- TMEM170B | c.*3563G>T | 3'UTR (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- TNFSF4 | c.*1412C>A | 3'UTR (SNP) | VAF 50/72 reads (69%) | called by muse, mutect2, varscan2
- TRIM24 | c.*269G>A | 3'UTR (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- VARS1 | c.522+36C>G | Intron (SNP) | VAF 57/128 reads (45%) | called by muse, mutect2, varscan2
